Gene-level copy-number profile of tumor specimen TCGA-QA-A7B7-01A from TCGA case TCGA-QA-A7B7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 48.3 years (17,636 days).
Specimen TCGA-QA-A7B7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.10238383-610c-40b3-a51e-c4a6e0b62888.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QA-A7B7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/901be2db-6321-49d7-bbe5-30817af03aeb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 14,564; copy number 2: 41,292; copy number 3: 3,847; copy number 4: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QA-A7B7-01A-11D-A32F-01): tumor purity 0.86, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:62,957,326–63,827,843, 13 genes (within-gene range 0–1): AC007098.1, OTX1, AC009501.1, AC009501.2, RPL27P5, DBIL5P2, WDPCP, Metazoa_SRP, MTFR2P1, AC016734.1, MDH1, PRELID1P6, RPS4XP5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 12,178. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
